Somatic mutation profile of tumor specimen TCGA-23-1121-01A (aliquot TCGA-23-1121-01A-01W-0486-08) from TCGA case TCGA-23-1121, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.0 years (18,983 days).
Specimen TCGA-23-1121-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60aeb8c3-1dbc-459f-9afd-7819c0de4c5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1121-10A (Blood Derived Normal), aliquot TCGA-23-1121-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1e80f3d-cb49-4c9a-99b5-e9804a87bf98

The open-access MAF lists 310 somatic variants for this specimen: 243 protein-altering or splice-affecting, 60 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 60, Nonsense Mutation 17, Splice Site 12, Frame Shift Del 9, RNA 5, Frame Shift Ins 3, In Frame Del 2, 3'UTR 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 210/353 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730880816, COSV62522204; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 134/164 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691037, CM087281, CM159290, COSV52670715, COSV52718021, COSV53252418; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.4342C>A p.Q1448K | Missense Mutation (SNP) | VAF 114/472 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV100229552; called by muse, mutect2, varscan2
- ABCB1 | c.2863G>T p.G955* | Nonsense Mutation (SNP) | VAF 198/413 reads (48%) | catalogued as COSV99714580; called by muse, mutect2, varscan2
- ABCB6 | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 301/310 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs1431623672, COSV99202516; called by muse, mutect2, varscan2
- ACP3 | c.1064G>A p.R355K | Missense Mutation (SNP) | VAF 215/939 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100313611; called by muse, mutect2, varscan2
- ACRBP | c.1596G>C p.Q532H | Missense Mutation (SNP) | VAF 148/270 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99976310; called by muse, mutect2, varscan2
- ADGRE5 | c.1352G>T p.S451I (on ENST00000242786 / NM_078481.4; = p.S358I on NM_001784.5) | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99663321; called by muse, varscan2
- ADGRF2 | c.613C>A p.P205T (on ENST00000296862 / NM_001368115.2; = p.P137T on NM_153839.7) | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV99731857; called by muse, mutect2, varscan2
- AGFG2 | c.1384A>G p.M462V | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.824); catalogued as COSV99499591; called by muse, mutect2, varscan2
- AHNAK2 | c.11945C>T p.A3982V | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.969); catalogued as rs987658740, COSV100319102; called by muse, mutect2, varscan2
- AKR1C4 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 92/422 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99578962; called by muse, mutect2, varscan2
- ALB | c.1496A>T p.K499I | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as COSV99892387; called by muse, mutect2, varscan2
- ALDH9A1 | c.1331C>G p.A444G | Missense Mutation (SNP) | VAF 101/609 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100699326; called by muse, mutect2, varscan2
- ALOX12B | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100047799, COSV59873591; called by muse, mutect2, varscan2
- ANKRD35 | c.155C>G p.S52W | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100841868, COSV62910458; called by muse, mutect2, varscan2
- ANO3 | c.1446G>A p.W482* | Nonsense Mutation (SNP) | VAF 167/575 reads (29%) | catalogued as COSV99846714; called by muse, mutect2, varscan2
- APOB | c.12374A>T p.D4125V | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV99268384; called by muse, mutect2, varscan2
- ARFGEF1 | c.5377G>T p.D1793Y | Missense Mutation (SNP) | VAF 19/373 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99140064; called by muse, mutect2
- ARPC3 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773333430, COSV99959606; called by muse, mutect2, varscan2
- ARSI | c.1656G>T p.K552N | Missense Mutation (SNP) | VAF 63/66 reads (95%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs1293031392, COSV100156137, COSV60817302; called by muse, mutect2, varscan2
- ATP5F1C | c.638-1G>C p.X213_splice | Splice Site (SNP) | VAF 78/358 reads (22%) | catalogued as COSV100184359, COSV100184420; called by muse, mutect2, varscan2
- ATP8B4 | c.2241A>C p.E747D | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV99467719; called by muse, mutect2, varscan2
- BAZ1A | c.3875G>T p.G1292V | Missense Mutation (SNP) | VAF 203/497 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.499); catalogued as COSV100701225; called by muse, mutect2, varscan2
- BCOR | c.4976G>A p.G1659E (on ENST00000378444 / NM_001123385.2; = p.G1625E on NM_017745.6) | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100654240; called by muse, mutect2, varscan2
- BMP2K | c.832T>G p.F278V | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100621762, COSV100622010; called by muse, mutect2, varscan2
- BRINP2 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762582867, COSV64180145; called by muse, mutect2, varscan2
- BRWD1 | c.5173G>C p.D1725H | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as rs759572995, COSV100314243; called by muse, mutect2, varscan2
- CACNA1A | c.917T>C p.F306S | Missense Mutation (SNP) | VAF 428/1924 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100803303; called by muse, mutect2, varscan2
- CACNA1C | c.6420G>C p.M2140I (on ENST00000399634 / NM_001167625.1; = p.M2069I on NM_000719.7) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV100222696; called by muse, mutect2
- CAD | c.2689T>G p.C897G | Missense Mutation (SNP) | VAF 164/594 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV99255858; called by muse, mutect2, varscan2
- CAMK2B | c.340A>T p.S114C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.152); catalogued as COSV99323598; called by muse, mutect2, varscan2
- CASZ1 | c.2321G>A p.G774E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV100682230; called by muse, mutect2
- CCDC89 | c.532C>A p.Q178K | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as COSV100320923; called by muse, varscan2
- CD180 | c.1400G>A p.G467D | Missense Mutation (SNP) | VAF 81/394 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99842428; called by muse, mutect2, varscan2
- CD74 | c.106C>G p.R36G | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as COSV50532603; called by mutect2, varscan2
- CDC123 | c.67A>G p.I23V | Missense Mutation (SNP) | VAF 133/159 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV99827246; called by muse, mutect2, varscan2
- CDC42EP3 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV99768003; called by muse, mutect2, varscan2
- CDCA7L | c.1196C>A p.P399Q | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100179781, COSV100181122; called by muse, mutect2, varscan2
- CDK5RAP2 | c.448C>G p.R150G | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs771565845, COSV100575763; called by muse, mutect2, varscan2
- CEACAM18 | c.582G>T p.R194S | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.171); catalogued as COSV101140742; called by muse, mutect2
- CHD4 | c.3113A>C p.K1038T (on ENST00000357008 / NM_001363606.2; = p.K1051T on NM_001273.5) | Missense Mutation (SNP) | VAF 181/499 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100539323, COSV58906025; called by muse, mutect2, varscan2
- CHD7 | c.1541G>C p.C514S | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.062); catalogued as rs748754045, COSV71110534; called by muse, mutect2
- COL5A3 | c.4670G>C p.G1557A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99319854; called by muse, varscan2
- COL6A6 | c.2113C>G p.L705V | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100651003; called by muse, mutect2, varscan2
- COL9A3 | c.148-2A>G p.X50_splice | Splice Site (SNP) | VAF 22/84 reads (26%) | catalogued as CS120464, CS991359, COSV99284524; called by muse, mutect2
- CREBL2 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV57428386; called by muse, mutect2, varscan2
- CREBL2 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57428032, COSV99963701; called by muse, varscan2
- CTR9 | c.1991G>T p.R664L | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV100797540; called by muse, mutect2, varscan2
- DAB2 | c.231+1G>A p.X77_splice | Splice Site (SNP) | VAF 164/947 reads (17%) | catalogued as COSV100297893; called by muse, mutect2, varscan2
- DEFB114 | c.59C>A p.T20K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.209); catalogued as COSV100435462; called by muse, mutect2, varscan2
- DELE1 | c.937A>T p.S313C | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV99520034; called by muse, mutect2, varscan2
- DENND1C | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs761566871, COSV57569959; called by muse, mutect2, varscan2
- DIP2B | c.4054G>A p.V1352M | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755001684, COSV56583702; called by muse, mutect2, varscan2
- DNAH10 | c.5657A>T p.Y1886F (on ENST00000409039; = p.Y1825F on NM_207437.3) | Missense Mutation (SNP) | VAF 74/374 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV101292851; called by muse, varscan2
- DNAJC14 | c.2051C>A p.P684H | Missense Mutation (SNP) | VAF 56/1358 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54478132, COSV99670872; called by muse, mutect2
- DPH2 | c.1022G>C p.C341S | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99356668; called by muse, mutect2, varscan2
- DPP4 | c.1679G>A p.R560K | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100859120; called by muse, mutect2, varscan2
- DTNBP1 | c.634T>C p.S212P | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.603); catalogued as COSV100161187; called by muse, mutect2, varscan2
- DUOXA1 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 224/399 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.758); catalogued as COSV99973593; called by muse, varscan2
- DYNAP | c.539C>T p.P180L (on ENST00000321600; = p.P154L on NM_173629.3) | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV100391917; called by muse, varscan2
- ECM1 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 134/513 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs190769895, COSV100681864, COSV100682333; called by muse, varscan2
- EDN1 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 158/1187 reads (13%) | catalogued as COSV101040345, COSV65080965; called by muse, mutect2, varscan2
- EGFL6 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 195/779 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as COSV100789967; called by muse, mutect2, varscan2
- ERGIC1 | c.21G>A p.R7= | Splice Region (SNP) | VAF 3382/3523 reads (96%) | catalogued as COSV67127284; called by muse, mutect2, varscan2
- EXOC2 | c.2624C>T p.S875L | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV100034275; called by muse, mutect2, varscan2
- FAM47A | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1224051046, COSV60497362; called by muse, mutect2, varscan2
- FAM83A | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 247/585 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); catalogued as COSV99414653; called by muse, mutect2, varscan2
- FASTKD1 | c.645A>C p.K215N | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV101328548; called by muse, mutect2, varscan2
- FCHO1 | c.485A>C p.D162A | Missense Mutation (SNP) | VAF 426/1310 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV99406504; called by muse, varscan2
- FCRL5 | c.195A>T p.E65D | Missense Mutation (SNP) | VAF 134/452 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.561); catalogued as COSV100709372; called by muse, mutect2, varscan2
- FCRL6 | c.1031C>A p.P344Q | Missense Mutation (SNP) | VAF 164/599 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as COSV100220427; called by muse, mutect2, varscan2
- FOXP3 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 26/46 reads (57%) | catalogued as COSV100873274; called by muse, mutect2, varscan2
- FSD2 | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100575311; called by muse, mutect2, varscan2
- GLTP | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100570262, COSV100570298; called by muse, mutect2, varscan2
- GPR101 | c.1480A>T p.T494S | Missense Mutation (SNP) | VAF 389/869 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.412); catalogued as COSV99981692; called by muse, mutect2, varscan2
- GPR19 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs764329998, COSV100197010; called by muse, mutect2, varscan2
- GPR4 | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100547220; called by muse, mutect2, varscan2
- GPR85 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.711); catalogued as rs1041947361, COSV51784462; called by muse, mutect2, varscan2
- GRK4 | c.572G>C p.R191T (on ENST00000398052 / NM_182982.3; = p.R159T on NM_005307.3) | Missense Mutation (SNP) | VAF 229/376 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100584301; called by muse, mutect2, varscan2
- GYS2 | c.707G>T p.R236M | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53924000, COSV99680297; called by muse, mutect2, varscan2
- H6PD | c.2276G>A p.S759N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as COSV101072532; called by muse, mutect2
- HAND1 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99164028; called by muse, mutect2, varscan2
- HHIPL2 | c.1085A>T p.D362V | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100597137; called by muse, mutect2
- HS3ST1 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV99137034; called by muse, mutect2, varscan2
- ICE1 | c.6220A>C p.K2074Q | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.45); catalogued as COSV99665877; called by muse, mutect2, varscan2
- IGSF3 | c.835A>C p.K279Q | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV100605152; called by muse, varscan2
- IL23R | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs970390731, COSV61374547; called by mutect2, varscan2
- ITGA11 | c.608T>G p.V203G | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100242267; called by muse, mutect2, varscan2
- ITGA8 | c.1970+1G>A p.X657_splice | Splice Site (SNP) | VAF 139/438 reads (32%) | catalogued as rs749220565, COSV100959707; called by muse, mutect2, varscan2
- JCAD | c.4031A>T p.D1344V | Missense Mutation (SNP) | VAF 168/194 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100948598; called by muse, mutect2, varscan2
- JUP | c.1914C>G p.N638K | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100159840; called by muse, mutect2, varscan2
- KAZN | c.1709C>G p.S570C | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs958616616, COSV101057377; called by muse, mutect2
- KCNK13 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 111/247 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs532635064, COSV99965946; called by muse, mutect2, varscan2
- KDM7A | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99135206; called by muse, varscan2
- KIAA1549 | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 269/1194 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.296); catalogued as COSV99652186; called by muse, mutect2, varscan2
- KIF17 | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 151/221 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99929878; called by muse, mutect2, varscan2
- KIF24 | c.3004G>C p.D1002H | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV99903628, COSV99903691; called by muse, mutect2
- KPNA6 | c.1009G>C p.A337P | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV101012636; called by muse, mutect2, varscan2
- KRTAP5-8 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 47/480 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as COSV101273172; called by muse, mutect2
- KYNU | c.1042-1G>T p.X348_splice | Splice Site (SNP) | VAF 69/174 reads (40%) | catalogued as COSV99933968, COSV99934063; called by muse, mutect2, varscan2
- LAMB1 | c.4483A>G p.K1495E | Missense Mutation (SNP) | VAF 471/780 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99741781; called by muse, mutect2, varscan2
- LATS1 | c.2755C>G p.P919A | Missense Mutation (SNP) | VAF 65/67 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99486778; called by muse, mutect2, varscan2
- LCT | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 175/591 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV99919412; called by muse, mutect2, varscan2
- LENEP | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99423102; called by muse, mutect2, varscan2
- LRCH3 | c.2052C>A p.D684E | Missense Mutation (SNP) | VAF 115/384 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100605284, COSV58396930; called by muse, mutect2, varscan2
- LRGUK | c.381A>T p.Q127H | Missense Mutation (SNP) | VAF 209/423 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV99604744; called by muse, mutect2, varscan2
- LRRC10 | c.749G>T p.R250I | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100825532; called by muse, mutect2, varscan2
- LRRC23 | c.683A>C p.H228P | Missense Mutation (SNP) | VAF 384/993 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99145362; called by muse, mutect2, varscan2
- MAGEC3 | c.1228A>T p.S410C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); catalogued as COSV100024829, COSV100026177; called by muse, mutect2, varscan2
- MARCHF4 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 38/1055 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99814853; called by muse, mutect2
- MAST4 | c.7534C>G p.R2512G (on ENST00000403625 / NM_001164664.2; = p.R2323G on NM_015183.3) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV99846076; called by muse, mutect2
- MCM10 | c.663C>G p.N221K (on ENST00000484800 / NM_182751.3; = p.N220K on NM_018518.5) | Missense Mutation (SNP) | VAF 245/819 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV101098491; called by muse, mutect2, varscan2
- MCM6 | c.2350-1G>T p.X784_splice | Splice Site (SNP) | VAF 43/106 reads (41%) | catalogued as COSV51470154; called by muse, mutect2, varscan2
- MED12 | c.1231A>G p.S411G | Missense Mutation (SNP) | VAF 302/676 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV100380168; called by muse, mutect2, varscan2
- MEST | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV99784435; called by muse, mutect2
- MIB1 | c.2015T>C p.L672P | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1210683122, COSV99839537; called by muse, mutect2, varscan2
- MKKS | c.159C>A p.Y53* | Nonsense Mutation (SNP) | VAF 28/32 reads (88%) | catalogued as COSV100726327; called by muse, mutect2, varscan2
- MUC3A | c.7781C>T p.P2594L | Missense Mutation (SNP) | VAF 199/818 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.192); catalogued as COSV100115489; called by muse, mutect2, varscan2
- MYLK | c.4316A>T p.D1439V | Missense Mutation (SNP) | VAF 262/628 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100659719; called by muse, varscan2
- MZT2A | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 82/1316 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as COSV100342969; called by muse, mutect2
- NAA35 | c.589C>G p.L197V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV100863458; called by muse, varscan2
- NCOR2 | c.3810C>G p.Y1270* | Nonsense Mutation (SNP) | VAF 135/268 reads (50%) | catalogued as COSV100657932; called by muse, varscan2
- NR4A1 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 89/261 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.799); catalogued as rs1440452084, COSV99671812; called by muse, mutect2, varscan2
- NRROS | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | catalogued as rs1446445186, COSV100145645; called by muse, mutect2
- NT5E | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 121/288 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100004376; called by muse, mutect2, varscan2
- NUS1 | c.450T>A p.D150E | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.043); catalogued as COSV100874970; called by muse, mutect2
- OBSCN | c.3065T>C p.L1022P | Missense Mutation (SNP) | VAF 263/286 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99484814; called by muse, mutect2, varscan2
- OR4C15 | c.336G>T p.M112I (on ENST00000314644; = p.M58I on NM_001001920.2) | Missense Mutation (SNP) | VAF 372/1425 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV100116138; called by muse, mutect2, varscan2
- OR4N2 | c.795C>A p.F265L | Missense Mutation (SNP) | VAF 114/398 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV100269698, COSV60051246; called by muse, mutect2, varscan2
- OR52D1 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100495353; called by muse, mutect2, varscan2
- OR56B4 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 141/391 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100337702, COSV57204737; called by muse, mutect2, varscan2
- OR5W2 | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV60616213; called by muse, mutect2, varscan2
- OR6N1 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); catalogued as COSV100625306; called by muse, mutect2, varscan2
- OXCT1 | c.1237T>C p.W413R | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99542817; called by muse, mutect2, varscan2
- PAPLN | c.3358C>T p.R1120* (on ENST00000554301; = p.R1093* on NM_173462.4) | Nonsense Mutation (SNP) | VAF 58/172 reads (34%) | catalogued as rs199905623; called by muse, mutect2, varscan2
- PCGF3 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100745503; called by muse, mutect2, varscan2
- PCGF3 | c.260A>T p.E87V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV100745505; called by muse, mutect2, varscan2
- PCSK2 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.244); catalogued as rs545158748, COSV99360865; called by muse, mutect2, varscan2
- PDK2 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 87/291 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs1051819691, COSV50304569; called by muse, mutect2, varscan2
- PDZRN4 | c.1727A>G p.D576G (on ENST00000402685 / NM_001164595.2; = p.D318G on NM_013377.4) | Missense Mutation (SNP) | VAF 216/651 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV100115593; called by muse, mutect2
- PEG3 | c.1999A>C p.I667L | Missense Mutation (SNP) | VAF 501/1257 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV99690592; called by muse, mutect2, varscan2
- PHF3 | c.2245T>G p.L749V | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100014071; called by muse, mutect2, varscan2
- PLA1A | c.1027G>A p.V343M | Missense Mutation (SNP) | VAF 134/671 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as rs750275676, COSV56331809, COSV99846114; called by muse, mutect2, varscan2
- PLEKHM3 | c.1326G>C p.Q442H | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.353); catalogued as rs773478409, COSV101216937; called by muse, mutect2, varscan2
- POLE2 | c.1243T>C p.F415L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.21); catalogued as COSV99365014; called by muse, mutect2, varscan2
- PPAT | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 89/420 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99947512; called by muse, mutect2, varscan2
- PPM1F | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99601744; called by muse, mutect2
- PPP1R32 | c.31T>A p.S11T | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as COSV100087987; called by muse, mutect2, varscan2
- PREX1 | c.3398A>T p.E1133V | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs758733786, COSV100906848; called by muse, mutect2, varscan2
- PRKACA | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100432329; called by muse, varscan2
- PTPRZ1 | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 164/589 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV66446919; called by muse, varscan2
- PUS7L | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100786626; called by muse, mutect2, varscan2
- RADX | c.1543A>G p.T515A | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as COSV100998929; called by muse, mutect2, varscan2
- RANBP3L | c.186A>T p.E62D | Missense Mutation (SNP) | VAF 70/647 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.536); catalogued as COSV99684090; called by muse, mutect2, varscan2
- RAPGEF6 | c.1189G>C p.V397L | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99728118; called by muse, varscan2
- RET | c.3314C>G p.A1105G | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.695); catalogued as CM1211267, COSV100394779, COSV60686357; called by muse, mutect2, varscan2
- RHAG | c.1220A>T p.K407M | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100006901; called by muse, mutect2, varscan2
- RNFT1 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as COSV99994568; called by muse, mutect2, varscan2
- RO60 | c.508A>C p.K170Q | Missense Mutation (SNP) | VAF 2015/2077 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100814449; called by muse, mutect2, varscan2
- RPL10L | c.472A>T p.K158* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100022780; called by muse, mutect2, varscan2
- SACS | c.5658C>G p.I1886M | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV101207758; called by muse, mutect2
- SBNO1 | c.1622T>C p.V541A (on ENST00000420886; = p.V540A on NM_018183.5) | Missense Mutation (SNP) | VAF 231/407 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.351); catalogued as COSV99929777; called by muse, mutect2, varscan2
- SDC2 | c.169T>A p.S57T | Missense Mutation (SNP) | VAF 228/1049 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100144054; called by muse, mutect2, varscan2
- SEC23B | c.674C>G p.P225R | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99358129; called by muse, mutect2, varscan2
- SELP | c.917G>T p.C306F | Missense Mutation (SNP) | VAF 176/710 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99741260; called by muse, mutect2, varscan2
- SH3BGRL | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100943503, COSV64621017, COSV64621276; called by muse, mutect2, varscan2
- SHMT2 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 28/481 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100197436; called by muse, mutect2
- SIAH3 | c.631C>G p.R211G | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101248069, COSV68552256; called by muse, mutect2, varscan2
- SIK3 | c.1963C>A p.H655N (on ENST00000445177 / NM_001366686.2; = p.H613N on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 371/730 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99408896; called by muse, mutect2, varscan2
- SLC1A3 | c.1565C>A p.P522Q | Missense Mutation (SNP) | VAF 44/711 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99468423; called by muse, mutect2
- SLC22A6 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 29/96 reads (30%) | catalogued as rs1383910173, COSV100842943; called by muse, mutect2, varscan2
- SLC2A11 | c.598G>T p.A200S (on ENST00000345044 / NM_001024938.4; = p.A207S on NM_030807.5) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs977340089, COSV99741909; called by muse, varscan2
- SLC2A13 | c.1546T>C p.Y516H | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1224016985, COSV99787246; called by muse, mutect2, varscan2
- SLC2A3 | c.363C>G p.I121M | Missense Mutation (SNP) | VAF 86/345 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV99306996; called by muse, mutect2, varscan2
- SLC38A3 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV101310009; called by muse, mutect2, varscan2
- SLC47A2 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV99450329; called by muse, mutect2, varscan2
- SMAP1 | c.119-1G>C p.X40_splice | Splice Site (SNP) | VAF 61/186 reads (33%) | catalogued as COSV100392026; called by muse, mutect2, varscan2
- SMG6 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.649); catalogued as rs146886918; called by muse, mutect2, varscan2
- SOGA1 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1286003725, COSV99415558; called by muse, mutect2, varscan2
- SOX5 | c.946G>T p.V316F | Missense Mutation (SNP) | VAF 267/433 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV58631637; called by muse, mutect2, varscan2
- SPTB | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 676/1712 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as COSV101072436; called by muse, mutect2, varscan2
- SPTBN1 | c.2630T>C p.I877T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV100443512; called by muse, mutect2, varscan2
- SRA1 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 204/416 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99782388; called by muse, mutect2, varscan2
- STIM2 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99403323; called by muse, mutect2, varscan2
- SYNE2 | c.17945A>C p.K5982T | Missense Mutation (SNP) | VAF 135/264 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100648552; called by muse, mutect2, varscan2
- TARS1 | c.454-1G>T p.X152_splice | Splice Site (SNP) | VAF 45/312 reads (14%) | catalogued as rs1561073288, COSV99466520; called by muse, mutect2, varscan2
- TAS2R40 | c.921G>T p.W307C | Missense Mutation (SNP) | VAF 12/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101283029, COSV101283032; called by muse, mutect2
- TBC1D10B | c.1697C>G p.S566* | Nonsense Mutation (SNP) | VAF 16/118 reads (14%) | catalogued as COSV99977258; called by muse, mutect2, varscan2
- TBPL2 | c.844G>C p.G282R | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99905588; called by muse, mutect2, varscan2
- TCF23 | c.465+1G>A p.X155_splice | Splice Site (SNP) | VAF 42/485 reads (9%) | catalogued as rs373445415; called by muse, mutect2
- TCP11L2 | c.406A>T p.I136F | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100135594; called by muse, mutect2, varscan2
- TDRKH | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV100162724; called by muse, mutect2
- TFCP2L1 | c.938A>G p.D313G | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV99748834; called by muse, mutect2, varscan2
- TIMM50 | c.598-1G>A p.X200_splice | Splice Site (SNP) | VAF 19/253 reads (8%) | catalogued as COSV58680194; called by muse, mutect2
- TJP2 | c.2045G>C p.R682P | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99601927; called by muse, mutect2, varscan2
- TK1 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99857425; called by muse, mutect2
- TP53I3 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs959212661, COSV99475522; called by muse, mutect2, varscan2
- TRANK1 | c.5932C>A p.Q1978K | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV100084921, COSV57160662; called by muse, mutect2
- TRIM9 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 151/375 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV100032275; called by muse, mutect2, varscan2
- TRPC3 | c.532G>A p.A178T (on ENST00000379645 / NM_001366479.2; = p.A105T on NM_003305.2) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99313567; called by muse, mutect2, varscan2
- TSHZ3 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV53683875, COSV99552902; called by muse, mutect2
- TTL | c.165G>T p.E55D | Missense Mutation (SNP) | VAF 300/1423 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); catalogued as COSV99271408, COSV99271653; called by muse, mutect2, varscan2
- TXLNA | c.571G>C p.A191P | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV101009924; called by muse, mutect2, varscan2
- UBE2O | c.3038C>G p.P1013R | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100039588; called by muse, varscan2
- UBQLNL | c.1195G>C p.A399P | Missense Mutation (SNP) | VAF 205/495 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as COSV100975711; called by muse, mutect2, varscan2
- UGT2A1 | c.1091C>G p.P364R | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684952; called by muse, mutect2, varscan2
- UNC79 | c.7399C>A p.L2467M (on ENST00000393151 / NM_001346218.2; = p.L2290M on NM_020818.5) | Missense Mutation (SNP) | VAF 29/760 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99829821, COSV99829996; called by muse, mutect2
- VCPIP1 | c.3278A>T p.D1093V | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100125805; called by muse, mutect2, varscan2
- VTA1 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs919714688, COSV62659126, COSV62660396; called by muse, mutect2
- VWC2 | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 59/278 reads (21%) | catalogued as COSV100514844; called by muse, mutect2, varscan2
- VWCE | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100076186, COSV57115907; called by muse, mutect2
- WASHC5 | c.1168A>G p.K390E | Missense Mutation (SNP) | VAF 109/417 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100573116; called by muse, mutect2, varscan2
- XRCC1 | c.194C>G p.S65* | Nonsense Mutation (SNP) | VAF 118/1680 reads (7%) | catalogued as COSV99486792; called by muse, mutect2
- XRCC2 | c.817G>C p.G273R | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100831709; called by muse, mutect2, varscan2
- ZBED1 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100586113, COSV100586231; called by muse, mutect2
- ZC3H10 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs201409280; called by muse, mutect2, varscan2
- ZFPM2 | c.1522A>T p.T508S | Missense Mutation (SNP) | VAF 137/1232 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.038); catalogued as COSV101023632; called by muse, mutect2, varscan2
- ZNF347 | c.765T>A p.N255K | Missense Mutation (SNP) | VAF 236/654 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV100498465; called by muse, mutect2
- ZNF347 | c.400G>T p.V134F | Missense Mutation (SNP) | VAF 407/1064 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV100498466; called by muse, mutect2, varscan2
- ZNF398 | c.1018G>C p.E340Q (on ENST00000475153 / NM_170686.3; = p.E169Q on NM_020781.4) | Missense Mutation (SNP) | VAF 29/518 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.655); catalogued as COSV100247078; called by muse, mutect2
- ZNF99 | c.2026C>A p.P676T | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV101233847, COSV101233989; called by muse, varscan2
- ABCC3 | c.1349_1368del p.P450Rfs*37 | Frame Shift Del (DEL) | VAF 349/1895 reads (18%) | called by mutect2, pindel, varscan2
- CSF3 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- DEFB106A | c.90del p.T32Hfs*20 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, varscan2
- DIP2C | c.697G>C p.A233P | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by mutect2, varscan2
- DNAH3 | c.6263_6275del p.L2088Pfs*41 | Frame Shift Del (DEL) | VAF 16/26 reads (62%) | called by mutect2, pindel, varscan2
- FLNA | c.6087_6097del p.H2029Qfs*32 (on ENST00000369850 / NM_001110556.2; = p.H2021Qfs*32 on NM_001456.3) | Frame Shift Del (DEL) | VAF 41/58 reads (71%) | called by mutect2, varscan2
- GNLY | c.255+2_255+14del p.X85_splice | Splice Site (DEL) | VAF 3/38 reads (8%) | called by mutect2, pindel
- HIRA | c.2308C>G p.P770A | Missense Mutation (SNP) | VAF 18/564 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2
- HSPA12B | c.469_474del p.T157_Q158del | In Frame Del (DEL) | VAF 64/108 reads (59%) | called by mutect2, pindel, varscan2
- IGSF10 | c.4332_4344del p.S1444Rfs*19 | Frame Shift Del (DEL) | VAF 38/294 reads (13%) | called by mutect2, pindel, varscan2
- NIPBL | c.3380del p.D1127Vfs*46 | Frame Shift Del (DEL) | VAF 48/352 reads (14%) | called by mutect2, pindel, varscan2
- PBRM1 | c.619_645+3del p.X207_splice | Splice Site (DEL) | VAF 13/120 reads (11%) | called by mutect2, pindel
- PSG2 | c.105_122del p.V36_Q41del | In Frame Del (DEL) | VAF 183/822 reads (22%) | called by mutect2, pindel, varscan2
- PTPN7 | c.996dup p.M333Dfs*24 (on ENST00000495688; = p.M372Dfs*24 on NM_002832.4 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 8/85 reads (9%) | called by mutect2, pindel
- PXYLP1 | c.735_750del p.C245* | Frame Shift Del (DEL) | VAF 21/107 reads (20%) | called by mutect2, pindel, varscan2
- RELN | c.10084C>A p.Q3362K | Missense Mutation (SNP) | VAF 36/1085 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2
- SH2D2A | c.581_594del p.A194Efs*84 | Frame Shift Del (DEL) | VAF 429/1931 reads (22%) | called by mutect2, pindel, varscan2
- SMG5 | c.1536_1537insACACA p.D513Tfs*6 | Frame Shift Ins (INS) | VAF 98/686 reads (14%) | called by pindel, varscan2
- TEX2 | c.1091_1094delinsGAATCACTA p.I364Rfs*19 | Frame Shift Ins (INS) | VAF 37/292 reads (13%) | called by pindel, varscan2*
- ZNF26 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ZNF675 | c.403_451del p.C135Kfs*14 | Frame Shift Del (DEL) | VAF 27/128 reads (21%) | called by mutect2, pindel
- ACBD3 | c.1422T>A p.P474= | Silent (SNP) | VAF 125/396 reads (32%) | catalogued as COSV100831169; called by muse, mutect2, varscan2
- AHCYL1 | c.198G>A p.S66= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as rs141483929; called by muse, mutect2, varscan2
- ATN1 | c.1818G>A p.T606= | Silent (SNP) | VAF 137/420 reads (33%) | catalogued as rs782338732, COSV100755975; called by muse, mutect2, varscan2
- C1QB | c.664C>T p.L222= | Silent (SNP) | VAF 330/901 reads (37%) | catalogued as rs144135717; called by muse, varscan2
- C6orf62 | c.540C>G p.L180= | Silent (SNP) | VAF 178/373 reads (48%) | catalogued as COSV100016144, COSV100016212; called by muse, mutect2, varscan2
- CALR | c.321C>A p.G107= | Silent (SNP) | VAF 95/501 reads (19%) | catalogued as COSV100331143; called by muse, mutect2, varscan2
- CARMIL3 | c.1303C>T p.L435= | Silent (SNP) | VAF 12/284 reads (4%) | catalogued as COSV100549903; called by muse, mutect2
- CNGA4 | c.372C>G p.P124= | Silent (SNP) | VAF 190/463 reads (41%) | catalogued as COSV101171888; called by muse, mutect2, varscan2
- CYP11B2 | c.879C>G p.L293= | Silent (SNP) | VAF 67/666 reads (10%) | catalogued as rs756402357, COSV100011435; called by muse, mutect2, varscan2
- DCAF11 | c.1467C>A p.V489= | Silent (SNP) | VAF 138/394 reads (35%) | catalogued as COSV100386879; called by muse, mutect2, varscan2
- EXOC2 | c.2217G>A p.Q739= | Silent (SNP) | VAF 34/895 reads (4%) | catalogued as COSV57873633; called by muse, mutect2
- FAT3 | c.10647C>G p.P3549= | Silent (SNP) | VAF 135/281 reads (48%) | catalogued as COSV99971543; called by muse, mutect2, varscan2
- FBXO41 | c.1764C>T p.V588= | Silent (SNP) | VAF 116/468 reads (25%) | catalogued as rs1414209939, COSV99721609; called by muse, mutect2
- FIGN | c.966C>T p.Y322= | Silent (SNP) | VAF 58/557 reads (10%) | catalogued as rs748434974, COSV60767969; called by muse, varscan2
- GABRB1 | c.750C>G p.T250= | Silent (SNP) | VAF 283/990 reads (29%) | catalogued as COSV99780645, COSV99783706; called by muse, mutect2, varscan2
- GAD1 | c.759C>G p.A253= | Silent (SNP) | VAF 101/256 reads (39%) | catalogued as COSV100713944; called by muse, mutect2, varscan2
- GPATCH2 | c.885A>T p.A295= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as COSV100861431; called by muse, mutect2, varscan2
- GRAMD1C | c.399C>T p.T133= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100823033; called by muse, mutect2, varscan2
- GRK7 | c.495T>C p.D165= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as COSV99380318; called by muse, mutect2, varscan2
- GTPBP6 | c.705G>A p.R235= | Silent (SNP) | VAF 72/115 reads (63%) | catalogued as COSV100397858; called by muse, mutect2, varscan2
- H2BC7 | c.159C>T p.T53= | Silent (SNP) | VAF 706/2966 reads (24%) | catalogued as rs968559631, COSV100587292; called by muse, varscan2
- HCK | c.909G>T p.L303= | Silent (SNP) | VAF 392/1072 reads (37%) | catalogued as COSV99394657; called by muse, mutect2, varscan2
- HIVEP2 | c.6105T>C p.S2035= | Silent (SNP) | VAF 72/293 reads (25%) | catalogued as COSV99175796; called by muse, mutect2, varscan2
- HSPG2 | c.5943C>T p.G1981= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as rs539388297, COSV101021331; called by muse, mutect2, varscan2
- IKBKE | c.345G>T p.V115= | Silent (SNP) | VAF 23/205 reads (11%) | catalogued as COSV100898397; called by muse, mutect2, varscan2
- IP6K3 | c.1014A>G p.R338= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as COSV99540209; called by muse, mutect2, varscan2
- KAT6A | c.4842C>T p.S1614= | Silent (SNP) | VAF 207/602 reads (34%) | catalogued as COSV99705977; called by muse, mutect2, varscan2
- KCNJ1 | c.261C>A p.A87= | Silent (SNP) | VAF 36/55 reads (65%) | catalogued as COSV100131501; called by muse, mutect2, varscan2
- KCNV2 | c.180C>T p.D60= | Silent (SNP) | VAF 46/53 reads (87%) | catalogued as rs1403529555, COSV66056391; ClinVar: uncertain significance; called by muse, mutect2
- KCTD13 | c.792G>A p.L264= | Silent (SNP) | VAF 50/120 reads (42%) | catalogued as COSV58157307; called by muse, mutect2, varscan2
- KLK13 | c.600C>T p.N200= | Silent (SNP) | VAF 539/1170 reads (46%) | catalogued as COSV99335469; called by muse, mutect2, varscan2
- KRT6A | c.1398C>A p.R466= | Silent (SNP) | VAF 44/1049 reads (4%) | catalogued as COSV100417270; called by muse, mutect2
- LIF | c.78C>T p.P26= | Silent (SNP) | VAF 45/404 reads (11%) | catalogued as rs759268992, COSV99969997; called by muse, mutect2, varscan2
- MAPK6 | c.1479A>C p.S493= | Silent (SNP) | VAF 151/348 reads (43%) | catalogued as COSV99959507; called by muse, mutect2, varscan2
- MED28 | c.501A>T p.A167= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV99403856; called by muse, mutect2, varscan2
- NEB | c.9309C>A p.T3103= | Silent (SNP) | VAF 109/341 reads (32%) | catalogued as COSV99428452; called by muse, mutect2, varscan2
- NGDN | c.936G>C p.R312= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as COSV101238938; called by muse, mutect2, varscan2
- OR2AK2 | c.246A>G p.A82= | Silent (SNP) | VAF 325/480 reads (68%) | catalogued as COSV100824352, COSV63552163; called by muse, mutect2, varscan2
- PCDHA1 | c.1848C>T p.G616= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1554118136, COSV100974517; called by muse, mutect2, varscan2
- PCDHB15 | c.1179A>G p.L393= | Silent (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- PRKRIP1 | c.99C>G p.L33= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as COSV100700362; called by muse, varscan2
- PTPRZ1 | c.3516C>A p.T1172= | Silent (SNP) | VAF 122/554 reads (22%) | catalogued as COSV101100888; called by muse, mutect2, varscan2
- PZP | c.2016G>A p.K672= | Silent (SNP) | VAF 44/311 reads (14%) | catalogued as COSV99739674; called by muse, mutect2, varscan2
- RELN | c.525G>A p.Q175= | Silent (SNP) | VAF 92/352 reads (26%) | catalogued as COSV100634994; called by muse, mutect2, varscan2
- RFTN1 | c.996G>A p.L332= | Silent (SNP) | VAF 97/315 reads (31%) | catalogued as COSV100489914; called by muse, mutect2, varscan2
- SLC16A6 | c.730C>T p.L244= | Silent (SNP) | VAF 33/178 reads (19%) | catalogued as COSV100517427; called by muse, mutect2, varscan2
- SLC38A3 | c.34C>T p.L12= | Silent (SNP) | VAF 83/178 reads (47%) | catalogued as rs781240063, COSV101310011; called by muse, mutect2, varscan2
- SOGA1 | c.1785C>T p.R595= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1210953712, COSV99415547; called by muse, mutect2, varscan2
- SSTR1 | c.1083T>C p.R361= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as rs1340666089; called by mutect2, varscan2
- STIM1 | c.1314C>A p.G438= | Silent (SNP) | VAF 27/236 reads (11%) | catalogued as COSV100331058; called by muse, mutect2, varscan2
- SVEP1 | c.5028A>T p.G1676= | Silent (SNP) | VAF 44/61 reads (72%) | catalogued as COSV100991075; called by muse, mutect2, varscan2
- SYCN | c.78C>T p.S26= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV100355899; called by muse, mutect2, varscan2
- TRPV3 | c.1737C>A p.I579= | Silent (SNP) | VAF 600/645 reads (93%) | catalogued as COSV100028213; called by muse, mutect2, varscan2
- TSEN34 | c.654G>A p.E218= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV99825112; called by muse, mutect2, varscan2
- TTN | c.51195C>T p.A17065= (on ENST00000591111; = p.A9641= on NM_003319.4) | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as rs1559671858, COSV100593375, COSV100632445; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- WDR62 | c.978C>T p.H326= | Silent (SNP) | VAF 61/159 reads (38%) | catalogued as COSV99544306; called by muse, mutect2, varscan2
- ZNF14 | c.1521A>C p.L507= | Silent (SNP) | VAF 247/929 reads (27%) | catalogued as COSV100694151; called by muse, mutect2, varscan2
- ZNF169 | c.312G>A p.S104= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as rs570567753, COSV61767625; called by muse, mutect2
- ZNF362 | c.972G>A p.Q324= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100987070; called by muse, mutect2, varscan2
- ZNF708 | c.1431G>A p.K477= | Silent (SNP) | VAF 55/233 reads (24%) | catalogued as rs775515841, COSV63606909, COSV63607982; called by muse, mutect2, varscan2
- AC245047.1 | n.97G>A | RNA (SNP) | VAF 202/626 reads (32%) | called by muse, mutect2, varscan2
- AC245884.12 | n.11G>T | RNA (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- CDKL1 | n.163G>T | RNA (SNP) | VAF 26/975 reads (3%) | called by muse, mutect2
- GPM6B | chrX:13772931 G>C | 3'Flank (SNP) | VAF 62/195 reads (32%) | catalogued as COSV100366581, COSV57425245; called by muse, mutect2, varscan2
- LARS2 | c.*287T>C | 3'UTR (SNP) | VAF 131/798 reads (16%) | catalogued as COSV99648341; called by muse, mutect2, varscan2
- MIR521-2 | n.48del | RNA (DEL) | VAF 61/178 reads (34%) | called by mutect2, pindel, varscan2
- XIST | n.7273A>G | RNA (SNP) | VAF 28/218 reads (13%) | catalogued as rs1481511294; called by muse, varscan2
